Somatic mutation profile of tumor specimen TCGA-PG-A917-01A (aliquot TCGA-PG-A917-01A-31D-A37N-09) from TCGA case TCGA-PG-A917, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.2 years (27,104 days).
Specimen TCGA-PG-A917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74f04fad-b3bc-4945-8d50-55414fb9cd27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PG-A917-11A (Solid Tissue Normal), aliquot TCGA-PG-A917-11A-11D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aade05d2-b559-4016-b171-057e4442d152

The open-access MAF lists 890 somatic variants for this specimen: 681 protein-altering or splice-affecting, 189 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 443, Silent 189, Frame Shift Del 141, Nonsense Mutation 35, Frame Shift Ins 27, Splice Site 15, In Frame Del 11, Intron 7, Splice Region 7, 3'UTR 5, 5'Flank 2, Translation Start Site 2.

Variants (750 of 890; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHEK2 | c.1114del p.Y372Tfs*20 (on ENST00000382580 / NM_001005735.2; = p.Y329Tfs*20 on NM_007194.4) | Frame Shift Del (DEL) | VAF 43/72 reads (60%) | catalogued as rs1569121048; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DIAPH1 | c.3268dup p.M1090Nfs*13 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | catalogued as rs1235751512; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KAT6A | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794000, COSV55907802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1554829003, COSV99695945; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RLIM | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569309459, CM151028, COSV100222889; ClinVar: pathogenic; called by muse, mutect2
- STXBP1 | c.664-1G>A p.X222_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as rs1554777464, COSV100964641, COSV64812143; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101036699; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCB8 | c.1966C>T p.R656W (on ENST00000297504 / NM_001282291.2; = p.R639W on NM_007188.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148536036; called by muse, mutect2, varscan2
- AC097636.1 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs200102944; called by muse, mutect2, varscan2
- ACBD3 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100830941; called by muse, mutect2, varscan2
- ACTL8 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100958545; called by muse, mutect2, varscan2
- ACTL9 | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100185197; called by muse, mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 21/58 reads (36%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM29 | c.1874G>A p.C625Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821940; called by muse, mutect2, varscan2
- ADAM8 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750746913, COSV101291633; called by muse, mutect2, varscan2
- ADAM8 | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | catalogued as COSV101291634; called by muse, mutect2, varscan2
- ADAMTS8 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as rs1470097692, COSV57293349; called by muse, mutect2
- ADCY8 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1403776150, COSV99651382; called by muse, mutect2, varscan2
- ADCY9 | c.3857A>G p.Q1286R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99569609; called by muse, mutect2, varscan2
- ADGRB2 | c.1780T>C p.Y594H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs1420043152, COSV99925869; called by muse, mutect2, varscan2
- ADRM1 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99438784; called by muse, mutect2, varscan2
- ADSS1 | c.741del p.K248Rfs*23 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs769542442; called by mutect2, pindel, varscan2
- AFAP1 | c.1924A>T p.S642C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100631273; called by muse, mutect2, varscan2
- AFMID | c.50_52del p.K17del | In Frame Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs746638950; called by pindel, varscan2
- AHSA1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV99375899; called by muse, mutect2, varscan2
- AKAP6 | c.5850G>T p.K1950N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55206606, COSV99799461; called by muse, mutect2, varscan2
- ALG1 | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99275534; called by muse, mutect2, varscan2
- AMDHD1 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV99900255; called by muse, mutect2, varscan2
- AMER3 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100366218; called by muse, mutect2, varscan2
- ANAPC7 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV101482846; called by muse, mutect2, varscan2
- ANKRD11 | c.1106del p.K369Rfs*58 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as COSV56371641; called by pindel, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD34A | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100041195; called by muse, mutect2, varscan2
- ANKS3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs765960466, COSV100172844; called by muse, mutect2, varscan2
- ANO8 | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99344218; called by muse, mutect2, varscan2
- AP2A1 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100571046; called by muse, mutect2, varscan2
- APBA1 | c.2442G>T p.E814D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99595707; called by muse, mutect2, varscan2
- API5 | c.1251A>G p.I417M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV101124515, COSV66633203; called by muse, mutect2, varscan2
- APOB | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99264525; called by muse, mutect2, varscan2
- APPL2 | c.351A>T p.Q117H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99314558; called by mutect2, varscan2
- ARHGAP45 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1327843468, COSV57434141; called by muse, mutect2, varscan2
- ARHGEF17 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs892433558, COSV99735101; called by muse, mutect2, varscan2
- ARHGEF18 | c.1991C>T p.P664L (on ENST00000359920 / NM_001130955.2; = p.P560L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149572002; called by muse, mutect2, varscan2
- ARHGEF19 | c.1298+2T>A p.X433_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99580169; called by muse, mutect2, varscan2
- ARID1A | c.4652G>A p.R1551H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs748819428, COSV61384854; called by muse, mutect2, varscan2
- ARMCX5 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99863338; called by muse, mutect2, varscan2
- ART1 | c.735dup p.F246Lfs*2 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs762428866; called by mutect2, varscan2
- ATAD5 | c.1487G>T p.R496I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100429773; called by muse, mutect2, varscan2
- ATCAY | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs1176122367, COSV100008566; called by muse, mutect2, varscan2
- ATP11A | c.736T>A p.S246T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV99367825; called by muse, mutect2, varscan2
- ATP13A3 | c.2419G>T p.E807* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99756574; called by muse, mutect2, varscan2
- ATP1A3 | c.2083C>T p.R695C (on ENST00000545399 / NM_001256214.2; = p.R682C on NM_152296.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486455; called by mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs769726180; called by mutect2, varscan2
- ATP6V0D2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); catalogued as rs1343831181, COSV53413606, COSV53416972; called by muse, mutect2, varscan2
- ATP8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650033, COSV54942586; called by muse, mutect2, varscan2
- ATP9B | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as COSV100303144; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- BAK1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645835; called by muse, mutect2, varscan2
- BBS2 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV99802242; called by muse, mutect2, varscan2
- BBS9 | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs188817948, COSV99626973; called by muse, mutect2, varscan2
- BCHE | c.1618A>G p.T540A | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52259913; called by muse, mutect2, varscan2
- BCL9L | c.477A>T p.E159D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV100599676; called by muse, mutect2, varscan2
- BCORL1 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99498813; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BNC2 | c.2483C>A p.S828Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.99); catalogued as COSV101032554; called by muse, mutect2, varscan2
- BOD1L1 | c.6258C>A p.S2086R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs373873288, COSV99238844; called by muse, mutect2, varscan2
- BPTF | c.1530T>A p.D510E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100074414; called by muse, mutect2, varscan2
- BRD1 | c.1468del p.A490Pfs*26 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV53458006; called by mutect2, pindel, varscan2
- BRPF1 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100121147; called by muse, mutect2, varscan2
- BSDC1 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100344480; called by muse, mutect2, varscan2
- BSN | c.2642C>A p.P881H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.319); catalogued as COSV99607727; called by muse, mutect2, varscan2
- BTAF1 | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV99795094; called by muse, mutect2, varscan2
- C12orf57 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as rs144915095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf70 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.091); catalogued as COSV99531229; called by muse, mutect2, varscan2
- C19orf57 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV58782023; called by muse, mutect2, varscan2
- C1orf109 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100787452; called by muse, mutect2, varscan2
- C1orf174 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147890429; called by muse, mutect2, varscan2
- C3AR1 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99368254; called by muse, mutect2, varscan2
- CA10 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200396465, COSV99562138; called by muse, mutect2, varscan2
- CA8 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs556165338, COSV58773721; called by muse, mutect2, varscan2
- CACNA2D4 | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); catalogued as COSV99765311; called by muse, mutect2, varscan2
- CAMSAP2 | c.2251C>T p.R751W (on ENST00000236925 / NM_001297707.2; = p.R740W on NM_203459.3) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1301967760, COSV99373044; called by muse, mutect2, varscan2
- CARD11 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs377658907; called by muse, mutect2, varscan2
- CARD9 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1268928951, COSV99395880; called by muse, mutect2, varscan2
- CASP1 | c.891T>A p.D297E (on ENST00000436863 / NM_033292.4; = p.D276E on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100782743; called by muse, mutect2, varscan2
- CASP8 | c.305+1G>A p.X102_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99964888; called by muse, mutect2, varscan2
- CC2D1A | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs527913042, COSV100528344; called by muse, mutect2, varscan2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC88C | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs372621845; called by muse, mutect2, varscan2
- CD40LG | c.673T>A p.L225M | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV101033454; called by muse, mutect2, varscan2
- CD5 | c.548del p.G183Vfs*28 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1266056996; called by mutect2, pindel
- CD74 | c.818_819del p.E273Vfs*83 (on ENST00000009530 / NM_001025159.2; = p.E209Vfs*83 on NM_004355.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs1331289215; called by pindel, varscan2
- CD93 | c.361dup p.E121Gfs*7 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | catalogued as rs762805003; called by mutect2, varscan2
- CDC42BPB | c.4734G>T p.L1578F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV100775309; called by muse, mutect2, varscan2
- CDCA2 | c.2824G>A p.V942M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs1405083781, COSV100398792; called by muse, mutect2, varscan2
- CDH12 | c.332T>G p.I111S | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201923, COSV66434244; called by muse, mutect2, varscan2
- CDH20 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs201138959, COSV99404766; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5534T>G p.L1845R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.294); catalogued as COSV100575249; called by muse, mutect2, varscan2
- CDX4 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100999120; called by muse, mutect2, varscan2
- CELSR3 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892763294, COSV50844897, COSV50847069; called by muse, mutect2, varscan2
- CEMIP | c.2099A>T p.H700L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99586368; called by muse, mutect2, varscan2
- CENATAC | c.857T>G p.F286C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782424650, COSV100548665; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPF | c.5291G>A p.G1764E | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100871596; called by muse, mutect2
- CENPJ | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101121476; called by muse, mutect2, varscan2
- CEP85L | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100874131; called by muse, mutect2, varscan2
- CEP97 | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs567332394, COSV59123806; called by muse, mutect2, varscan2
- CERCAM | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs752039692, COSV100863906; called by muse, mutect2, varscan2
- CFAP100 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100729136; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP47 | c.4280C>T p.A1427V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545088; called by muse, mutect2, varscan2
- CHML | c.682A>T p.R228W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100087173; called by muse, mutect2, varscan2
- CHRNB2 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.692); catalogued as COSV100872571; called by muse, mutect2, varscan2
- CHST3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs772881284, COSV100910416; called by muse, mutect2, varscan2
- CHST3 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs1256221665, COSV100910417, COSV64151718; called by muse, mutect2, varscan2
- CIRBP | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs774624754, COSV100309731; called by muse, mutect2, varscan2
- CKAP4 | c.589G>T p.V197F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1490428690, COSV100952388, COSV100952418; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs754415052; called by mutect2, varscan2
- CLDN15 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100385199; called by muse, mutect2, varscan2
- CLEC4D | c.241T>A p.W81R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100222932; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSPN | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99230549; called by muse, mutect2, varscan2
- CNGB1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs1404626209, COSV99202253; called by muse, mutect2, varscan2
- CNNM4 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100998637; called by mutect2, varscan2
- CNTN5 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs182344400; called by muse, mutect2, varscan2
- COBL | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471799; called by muse, mutect2, varscan2
- COL5A3 | c.1442dup p.G482Wfs*66 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | catalogued as rs774328155; called by mutect2, pindel
- COL9A2 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV101025628; called by muse, mutect2, varscan2
- CORO1A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.242); catalogued as rs775464405, COSV99531907; called by muse, mutect2, varscan2
- CPEB4 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.98); catalogued as rs764316983, COSV54173558; called by muse, mutect2, varscan2
- CRYBA1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778535481, COSV56600613; called by muse, mutect2, varscan2
- CRYBG1 | c.2852C>A p.S951Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100954421, COSV64810861; called by muse, mutect2, varscan2
- CSGALNACT1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100174681; called by muse, mutect2, varscan2
- CSKMT | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100649043, COSV63473520; called by muse, mutect2, varscan2
- CSMD3 | c.6875G>A p.G2292D (on ENST00000297405 / NM_001363185.1; = p.G2188D on NM_052900.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs951593485, COSV99828991, COSV99840533; called by muse, mutect2, varscan2
- CTCF | c.143del p.G48Vfs*14 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as COSV50489849, COSV99864074; called by mutect2, pindel, varscan2
- CTNND1 | c.2222C>T p.A741V (on ENST00000399050 / NM_001085458.2; = p.A735V on NM_001331.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100649943; called by muse, mutect2, varscan2
- CTNND2 | c.2692G>A p.V898M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58864026; called by muse, mutect2, varscan2
- CTSF | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755154475, COSV100074182; called by muse, mutect2, varscan2
- CYP3A4 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV100315529; called by muse, mutect2, varscan2
- CYP3A7 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748017013, COSV60480698, COSV60482109; called by muse, mutect2, varscan2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs753942205; called by pindel, varscan2
- CYSLTR2 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV99935171; called by muse, mutect2, varscan2
- DAPP1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.301); catalogued as COSV99596727; called by muse, mutect2, varscan2
- DCBLD2 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs763960722, COSV100471776; called by muse, mutect2, varscan2
- DCHS1 | c.4880C>A p.P1627Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100201787; called by muse, mutect2, varscan2
- DCLK1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs373217123; called by mutect2, varscan2
- DDHD1 | c.1171C>T p.R391* (on ENST00000323669; = p.R588* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1394288187, COSV100079262; called by muse, mutect2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX41 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1271915654, COSV100286467; called by muse, mutect2, varscan2
- DDX54 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100013700; called by muse, mutect2, varscan2
- DDX54 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs763022316, COSV58373259; called by muse, mutect2, varscan2
- DHX16 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs778527121, COSV100905157; called by muse, mutect2
- DHX29 | c.2189T>C p.L730S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99287114; called by muse, mutect2, varscan2
- DHX34 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV100169377; called by muse, mutect2, varscan2
- DHX57 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as rs143143351; called by muse, mutect2, varscan2
- DHX9 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV100841308; called by muse, varscan2
- DHX9 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV100841309; called by muse, varscan2
- DIS3L | c.1103C>T p.T368I (on ENST00000319212 / NM_001143688.3; = p.T285I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs751011509, COSV100055017; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 23/52 reads (44%) | catalogued as rs756156984; called by mutect2, varscan2
- DLGAP1 | c.2516A>T p.Q839L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228918; called by muse, mutect2, varscan2
- DNAH7 | c.9291G>T p.K3097N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100414445; called by muse, mutect2, varscan2
- DNAH7 | c.9025A>T p.S3009C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100414446; called by muse, mutect2, varscan2
- DNAH9 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99304140, COSV99304908; called by muse, mutect2, varscan2
- DNHD1 | c.14149A>G p.T4717A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV99599688; called by muse, mutect2, varscan2
- DOCK10 | c.3270C>A p.T1090= | Splice Region (SNP) | VAF 14/37 reads (38%) | catalogued as rs1234758810, COSV99288453; called by muse, mutect2, varscan2
- DOCK11 | c.4936G>A p.A1646T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV99353269; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs782552436; called by pindel, varscan2
- DPT | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV100892116; called by muse, mutect2, varscan2
- DST | c.20548C>T p.R6850W (on ENST00000361203 / NM_001374722.1; = p.R4547W on NM_015548.5) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs535961631, COSV99753062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOX1 | c.4309C>T p.R1437* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs776076197, COSV99334327; called by muse, mutect2, varscan2
- E2F1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99864595; called by muse, mutect2, varscan2
- ECPAS | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.113); catalogued as COSV99397801; called by muse, mutect2, varscan2
- EEF1A1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100303240; called by muse, mutect2, varscan2
- EFL1 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV99186553; called by muse, mutect2, varscan2
- EIF4A3 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99484005; called by muse, mutect2, varscan2
- ELAC2 | c.582C>A p.H194Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100568402; called by muse, mutect2, varscan2
- EML4 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100580760; called by muse, mutect2, varscan2
- ENPP2 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.434); catalogued as rs757880591, COSV99307860; called by muse, mutect2, varscan2
- ENTPD1 | c.1326+1G>A p.X442_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100967439; called by muse, mutect2, varscan2
- EPCAM | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99764078; called by muse, mutect2, varscan2
- EPHX1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99688804; called by muse, mutect2, varscan2
- ERBB2 | c.3476C>T p.A1159V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99507184; called by muse, mutect2, varscan2
- ERC1 | c.2450G>A p.R817Q (on ENST00000360905 / NM_178040.4; = p.R789Q on NM_178039.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs767843629, COSV61696329; called by muse, mutect2, varscan2
- ESYT2 | c.2122A>T p.I708F (on ENST00000613624; = p.I632F on NM_020728.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV99276385; called by muse, mutect2, varscan2
- ETV1 | c.414dup p.T139Hfs*24 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs769886672; called by mutect2, varscan2
- ETV5 | c.485A>T p.H162L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100112165; called by muse, mutect2, varscan2
- F2RL2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs202236954, COSV99166858; called by muse, mutect2, varscan2
- F2RL3 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781145358, COSV99935176; called by muse, mutect2, varscan2
- FADS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99608518; called by muse, mutect2, varscan2
- FAM120C | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100069757; called by muse, mutect2, varscan2
- FAM155B | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99368245; called by muse, mutect2, varscan2
- FAM47C | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100792400; called by muse, mutect2, varscan2
- FAM83C | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100981536; called by muse, mutect2, varscan2
- FAN1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV100755888; called by muse, mutect2, varscan2
- FASN | c.6428T>G p.V2143G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100147527; called by muse, mutect2, varscan2
- FAT3 | c.9473C>A p.P3158H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99963645; called by muse, mutect2, varscan2
- FAT4 | c.2425G>T p.G809* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV67904047; called by muse, mutect2, varscan2
- FBLN2 | c.1434C>A p.H478Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99851576; called by muse, mutect2, varscan2
- FBN3 | c.4279C>T p.R1427C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs761789801, COSV99560339; called by muse, mutect2, varscan2
- FBXW7 | c.1398T>A p.C466* (on ENST00000281708 / NM_001349798.2; = p.C386* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99655317; called by muse, mutect2, varscan2
- FCGBP | c.12146G>A p.R4049H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs375256745; called by muse, mutect2, varscan2
- FGA | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV100120184; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FKBP10 | c.1276del p.Q426Rfs*10 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as CX128961; called by mutect2, pindel, varscan2
- FLG | c.4453G>A p.G1485S | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs200740047, COSV64237422; called by muse, mutect2, varscan2
- FMN1 | c.4229G>A p.R1410H (on ENST00000616417 / NM_001277313.2; = p.R1187H on NM_001103184.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs767520219, COSV100568233; called by muse, mutect2, varscan2
- FMNL1 | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs201370247, COSV58959626; called by muse, mutect2, varscan2
- FMNL2 | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV99979195; called by muse, mutect2, varscan2
- FOLH1 | c.1826A>T p.D609V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99922914; called by muse, mutect2, varscan2
- FOXA1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV51644353; called by muse, mutect2, varscan2
- FOXO1 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs745385825, COSV65425237; called by muse, mutect2, varscan2
- FRAS1 | c.9859G>T p.G3287W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349758; called by muse, mutect2, varscan2
- FREM1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV101084045; called by muse, mutect2, varscan2
- GABRR1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs763072691, COSV101033809; called by muse, mutect2, varscan2
- GAL3ST2 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.787); catalogued as rs1489815698, COSV99510810; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs758551787; called by mutect2, varscan2
- GCC2 | c.4246T>C p.S1416P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV100565336; called by mutect2, varscan2
- GDF11 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs748876101, COSV57690882; called by muse, mutect2, varscan2
- GINS2 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV99497989; called by muse, mutect2, varscan2
- GJA3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs541065387, COSV53834979; called by muse, mutect2, varscan2
- GLYATL1 | c.379C>T p.H127Y (on ENST00000317391 / NM_001354699.1; = p.H158Y on NM_080661.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100265209, COSV55611846; called by muse, mutect2, varscan2
- GOLGA6A | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as rs1353905297; called by muse, mutect2, varscan2
- GOLGA6B | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as rs1451116245; called by muse, mutect2, varscan2
- GOLGB1 | c.2838del p.E947Sfs*20 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs774978171; called by mutect2, pindel
- GPC4 | c.1124C>A p.T375N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100895431; called by muse, mutect2, varscan2
- GPKOW | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV50244127, COSV99332551; called by muse, mutect2, varscan2
- GRPR | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100977644; called by muse, varscan2
- GSPT2 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100468020; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTF3C3 | c.1831+2T>C p.X611_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99826582; called by muse, mutect2, varscan2
- GTPBP2 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100199881; called by muse, mutect2, varscan2
- GUCY1B1 | c.1677G>T p.K559N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1432155945, COSV100025407; called by muse, mutect2, varscan2
- HDAC6 | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57807081; called by muse, mutect2, varscan2
- HECW1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs938089850, COSV67829529; called by muse, mutect2, varscan2
- HEG1 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV100230271; called by muse, mutect2, varscan2
- HGS | c.2019C>T p.N673= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs760394413, COSV61269578; called by muse, mutect2, varscan2
- HKDC1 | c.1628T>G p.V543G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100664441, COSV63576777; called by muse, mutect2, varscan2
- HLX | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100854682, COSV65044779; called by muse, mutect2, varscan2
- HMCN1 | c.11123C>T p.T3708I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV99626164; called by muse, mutect2, varscan2
- HMGN5 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as COSV100814812; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs761272507; called by mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXD4 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as COSV100106751; called by muse, mutect2, varscan2
- HS3ST2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as COSV99757816; called by muse, mutect2, varscan2
- ICAM5 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs1306500851, COSV55747710; called by muse, mutect2, varscan2
- IGF1R | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99150300; called by muse, mutect2, varscan2
- IGHV3-16 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1442867205; called by muse, mutect2, varscan2
- IPO11 | c.2766G>T p.L922= | Splice Region (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100320416; called by muse, mutect2
- IPO11 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100320418; called by muse, mutect2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs771739474; called by mutect2, varscan2
- IRAK4 | c.1308T>A p.C436* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV101471805, COSV71210388; called by muse, mutect2, varscan2
- IRGC | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs375536082; called by muse, mutect2, varscan2
- ITPKC | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99648541; called by muse, mutect2, varscan2
- ITPRIP | c.383del p.G128Afs*48 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs751596276; called by mutect2, pindel, varscan2
- JPH2 | c.1170-2A>C p.X390_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100881655; called by muse, mutect2, varscan2
- JPH3 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs920244359, COSV52467402; called by muse, mutect2, varscan2
- KAT6A | c.3260G>A p.R1087H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs138322320; called by muse, mutect2, varscan2
- KCNA4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs775798928, COSV60250783; called by muse, mutect2, varscan2
- KCNA6 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as rs762449022, COSV99768460; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNH4 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV99236942; called by muse, mutect2, varscan2
- KCNIP4 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.107); catalogued as rs375511471, COSV100749144; called by muse, mutect2, varscan2
- KCNJ4 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100341068; called by muse, mutect2, varscan2
- KCNMA1 | c.3145G>A p.A1049T (on ENST00000286628 / NM_001161352.2; = p.A991T on NM_002247.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs199586877, COSV99695944; called by muse, mutect2, varscan2
- KDM6A | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100937995, COSV100938723; called by muse, mutect2, varscan2
- KDM6B | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs377466652; called by muse, mutect2, varscan2
- KIAA1109 | c.6641T>C p.M2214T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV99149755; called by muse, mutect2, varscan2
- KIF15 | c.4013A>G p.E1338G | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100392654; called by muse, mutect2, varscan2
- KIF3B | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100996348; called by muse, mutect2, varscan2
- KIF4A | c.3692C>T p.A1231V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100978574; called by muse, mutect2, varscan2
- KIF9 | c.1855G>A p.A619T (on ENST00000265529 / NM_001377474.1; = p.A554T on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99646501; called by muse, mutect2, varscan2
- KIRREL1 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1423205207, COSV63285747; called by muse, mutect2, varscan2
- KLHL28 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100753032; called by muse, mutect2, varscan2
- KLHL30 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573206585, COSV59977256; called by muse, mutect2, varscan2
- KLK13 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335213; called by muse, varscan2
- KLK15 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100032599; called by muse, mutect2, varscan2
- KMT2B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV52892583; called by muse, mutect2, varscan2
- KPNA6 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV101012461; called by muse, mutect2, varscan2
- L3MBTL3 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695844; called by muse, varscan2
- LAMA1 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs945345901, COSV67539963; called by muse, mutect2, varscan2
- LAMP2 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99568345; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs746633076; called by mutect2, varscan2
- LMTK3 | c.2768T>C p.V923A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV99540160; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs746133895; called by mutect2, varscan2
- LRBA | c.8137T>A p.L2713M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100841162; called by muse, mutect2
- LRRC14 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs1377557894, COSV99467255; called by muse, mutect2, varscan2
- LSM11 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99643902, COSV99643968; called by muse, mutect2, varscan2
- LTBP3 | c.1802G>A p.C601Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs757530025, COSV100099260; called by muse, mutect2, varscan2
- LTN1 | c.4874C>T p.T1625M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); catalogued as rs367755686; called by muse, mutect2, varscan2
- LTO1 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs568706175, COSV99654048; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- MAN1C1 | c.1208C>A p.S403* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99848011; called by muse, mutect2, varscan2
- MAP1A | c.4641G>T p.K1547N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100288333; called by muse, mutect2, varscan2
- MAP2K4 | c.942T>A p.F314L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100796162; called by muse, mutect2, varscan2
- MBD3L1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99977955; called by muse, mutect2, varscan2
- MCM5 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760371424, COSV99331569; called by muse, mutect2, varscan2
- MDH2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs782507132, COSV100242629; called by muse, mutect2
- MDN1 | c.12191T>C p.M4064T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV101020972; called by muse, mutect2, varscan2
- MED1 | c.4547G>A p.R1516Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.122); catalogued as rs1274447322, COSV56127280; called by muse, mutect2, varscan2
- MED13L | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99928263; called by muse, mutect2, varscan2
- MEGF8 | c.6428dup p.Q2144Pfs*17 (on ENST00000251268 / NM_001271938.2; = p.Q2077Pfs*17 on NM_001410.3) | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | catalogued as rs1258909672; called by mutect2, varscan2
- MEX3C | c.1259C>A p.T420N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV101346208; called by muse, mutect2, varscan2
- MGLL | c.362A>T p.H121L (on ENST00000398104 / NM_001003794.2; = p.H131L on NM_007283.6) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99411650; called by muse, mutect2, varscan2
- MIA2 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.287); catalogued as COSV99697442; called by muse, mutect2, varscan2
- MIA3 | c.5675C>T p.S1892F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100388141; called by muse, mutect2, varscan2
- MINK1 | c.3566C>G p.A1189G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1400695187, COSV53419135, COSV99545206; called by muse, mutect2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs546807245; called by mutect2, varscan2
- MMP20 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV99497525; called by muse, mutect2, varscan2
- MRAS | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100003624; called by muse, mutect2, varscan2
- MSH6 | c.2147_2148del p.T716Sfs*39 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs786204048; called by pindel, varscan2
- MTMR6 | c.1208G>A p.C403Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV67808772; called by muse, mutect2, varscan2
- MTMR6 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101110740; called by muse, mutect2, varscan2
- MTUS1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100029228; called by muse, mutect2, varscan2
- MUCL3 | c.1339T>C p.W447R (on ENST00000304311; = p.W1323R on NM_080870.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100423986; called by muse, mutect2
- MYCBP2 | c.6991C>T p.R2331* (on ENST00000357337; = p.R2369* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV62015332; called by muse, mutect2, varscan2
- MYCBP2 | c.5375C>T p.A1792V (on ENST00000357337; = p.A1830V on NM_015057.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100629621; called by muse, mutect2, varscan2
- MYH11 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs765885909, COSV100258149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV99193721; called by muse, mutect2, varscan2
- MYO1D | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV59017313; called by muse, mutect2, varscan2
- MYO5B | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs746376479, COSV99544066; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs763929397; called by mutect2, varscan2
- NBAS | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs557345395, COSV55712787; called by muse, mutect2
- NCKAP5 | c.202del p.A68Pfs*6 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs1456601728; called by mutect2, pindel, varscan2
- NCOR1 | c.3552G>T p.K1184N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99248543; called by muse, mutect2, varscan2
- NEDD9 | c.2414C>A p.T805K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV101060751, COSV101060803; called by muse, mutect2, varscan2
- NFATC2IP | c.787dup p.R263Pfs*12 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs765645344; called by mutect2, pindel, varscan2
- NFKBIL1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV100385379; called by muse, mutect2, varscan2
- NHLH1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV57484148; called by muse, mutect2
- NLRP12 | c.2963A>G p.E988G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100145034; called by muse, mutect2, varscan2
- NMBR | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99237161; called by muse, mutect2, varscan2
- NOCT | c.191-2A>G p.X64_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99763787; called by muse, mutect2, varscan2
- NOD2 | c.1583dup p.D529Rfs*50 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- NPC1L1 | c.3557G>T p.W1186L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99203618; called by muse, mutect2, varscan2
- NPHP4 | c.3416C>A p.P1139Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976796; called by muse, mutect2, varscan2
- NPNT | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99974858; called by muse, mutect2, varscan2
- NRXN1 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100640127, COSV60500915, COSV60527965; called by muse, mutect2, varscan2
- NRXN3 | c.1685G>A p.R562H (on ENST00000335750 / NM_001330195.2; = p.R189H on NM_004796.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs369032353; called by muse, mutect2, varscan2
- NSD3 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100388544; called by muse, mutect2, varscan2
- NUAK1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs552453023, COSV99776792; called by muse, mutect2, varscan2
- NUP188 | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV101001259; called by muse, mutect2, varscan2
- NUP210L | c.3675T>A p.D1225E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV99667549; called by muse, mutect2, varscan2
- NUP58 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs368369763; called by muse, mutect2, varscan2
- NXPE1 | c.1163T>C p.L388P (on ENST00000424269; = p.L246P on NM_152315.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761268613, COSV99320115; called by muse, mutect2, varscan2
- OASL | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV99984476; called by muse, mutect2, varscan2
- OCEL1 | c.289dup p.R97Pfs*21 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | catalogued as rs761699990; called by mutect2, pindel, varscan2
- OPRD1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs370180812, COSV52381623, COSV99330529; called by muse, mutect2, varscan2
- OR10V1 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100275686; called by muse, varscan2
- OR13C3 | c.737del p.F246Sfs*13 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs764206746; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs761899382; called by mutect2, varscan2
- OR4C15 | c.728C>T p.T243I (on ENST00000314644; = p.T189I on NM_001001920.2) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.105); catalogued as rs769109377, COSV100115487, COSV58951093; called by muse, mutect2, varscan2
- OR52N1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409825181, COSV100398627, COSV104395277; called by muse, mutect2, varscan2
- OR6B1 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101281641; called by muse, mutect2, varscan2
- OR8H2 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100542218; called by muse, mutect2, varscan2
- OTP | c.119del p.G40Afs*36 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as COSV60569956; called by mutect2, pindel, varscan2
- PAFAH1B2 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs752992388, COSV59166810; called by muse, mutect2, varscan2
- PALD1 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs189614985, COSV54980845; called by muse, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | catalogued as rs1564621823; called by mutect2, varscan2
- PAQR9 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503730; called by muse, mutect2, varscan2
- PAQR9 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100503731; called by muse, mutect2, varscan2
- PARPBP | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100569080; called by muse, mutect2, varscan2
- PAX8 | c.1228T>A p.Y410N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99639279; called by muse, mutect2
- PCDH19 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as CM122388, COSV99719317; called by muse, mutect2, varscan2
- PCDH19 | c.427A>T p.S143C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99719322; called by muse, mutect2, varscan2
- PCIF1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100976006; called by muse, mutect2, varscan2
- PCLAF | c.312T>G p.D104E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.419); catalogued as COSV100256898; called by muse, mutect2, varscan2
- PDCD2 | c.728A>T p.K243M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV99388411; called by muse, varscan2
- PDCD2 | c.663A>T p.E221D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99388415; called by muse, varscan2
- PENK | c.138+1G>T p.X46_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100152242; called by muse, mutect2, varscan2
- PER1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs751777997, CM166889, COSV100424383; called by muse, mutect2, varscan2
- PGAP6 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs369972725; called by muse, mutect2, varscan2
- PGGT1B | c.48G>C p.E16D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV101100403; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF14 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101301785; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | catalogued as rs769717544; called by mutect2, varscan2
- PHRF1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs374494964; called by mutect2, varscan2
- PIK3C2B | c.2005del p.L669Cfs*28 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs1180702150; called by mutect2, pindel, varscan2
- PILRA | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs761680244, COSV99546342; called by muse, mutect2, varscan2
- PITPNM3 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99338123; called by muse, mutect2, varscan2
- PLD3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs139707894, CM140826; called by muse, mutect2, varscan2
- PLEC | c.1531C>T p.H511Y (on ENST00000322810 / NM_201380.4; = p.H401Y on NM_000445.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV100512235; called by muse, mutect2, varscan2
- PLEKHH2 | c.2152A>G p.K718E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99174479; called by muse, mutect2, varscan2
- PLS3 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99171623; called by muse, mutect2, varscan2
- PLXNA1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99302641; called by muse, mutect2, varscan2
- PLXNA1 | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs765712162, COSV99302642; called by muse, mutect2, varscan2
- PLXNA2 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs202043088, COSV65441648; called by muse, mutect2, varscan2
- PLXNA3 | c.2809T>C p.F937L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100859862; called by muse, mutect2, varscan2
- PLXNA4 | c.3703A>G p.S1235G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100323248; called by muse, mutect2, varscan2
- PLXNB2 | c.4579T>C p.S1527P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100833926; called by muse, mutect2, varscan2
- PNP | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100828944, COSV104422169; called by muse, mutect2, varscan2
- PODN | c.1327A>G p.I443V (on ENST00000395871; = p.I395V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100439420; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 28/59 reads (47%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLD3 | c.1239T>A p.S413R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99737795; called by muse, mutect2, varscan2
- POLG | c.3239G>A p.S1080N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as CM136295, CM142208, COSV99174587; called by muse, varscan2
- POLN | c.608T>G p.L203W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101242485; called by muse, mutect2, varscan2
- POLR1F | c.932dup p.K312Efs*6 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs775851473; called by mutect2, varscan2
- POR | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as rs771477130, COSV100115521; called by muse, mutect2, varscan2
- POU4F1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV101020490; called by muse, mutect2, varscan2
- POU5F2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV101232691; called by muse, mutect2, varscan2
- PPIL6 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372432146, COSV70022277; called by muse, mutect2, varscan2
- PPM1D | c.1806_1809del p.C603Ffs*21 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs745470366; called by mutect2, varscan2
- PPP1R26 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs771384231, COSV100778024; called by muse, mutect2, varscan2
- PRG4 | c.2396C>A p.P799H | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1249803054, COSV100798142; called by muse, mutect2, varscan2
- PRKAG2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs1177945294, COSV55224970, COSV55245151; called by muse, mutect2, varscan2
- PRKCD | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs200939049; called by muse, mutect2, varscan2
- PRRC2C | c.719C>T p.A240V (on ENST00000367742; = p.A238V on NM_015172.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100144921; called by muse, mutect2, varscan2
- PSD2 | c.538del p.L180Sfs*56 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1361260068, COSV51214782; called by mutect2, pindel, varscan2
- PTBP2 | c.965A>C p.N322T (on ENST00000426398 / NM_001300986.2; = p.N314T on NM_021190.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV100930190; called by muse, mutect2, varscan2
- PTPN12 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); catalogued as COSV99950191; called by muse, mutect2, varscan2
- PTPRA | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776115054, COSV99399431; called by muse, mutect2, varscan2
- PTPRB | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs763542317, COSV99716449; called by muse, mutect2, varscan2
- PTPRK | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs201423083; called by muse, mutect2, varscan2
- PTPRN2 | c.162C>T p.N54= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs531843701, COSV101234014; called by muse, mutect2, varscan2
- PUM1 | c.2677A>G p.M893V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99927705; called by muse, mutect2, varscan2
- RAB40C | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.302); catalogued as COSV99937626; called by muse, mutect2, varscan2
- RABGEF1 | c.516G>T p.Q172H (on ENST00000439720 / NM_001287061.2; = p.Q159H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99534625; called by muse, mutect2, varscan2
- RAD54L2 | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV56576990, COSV99620952; called by muse, mutect2, varscan2
- RAI1 | c.3328A>G p.S1110G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99883655; called by mutect2, varscan2
- RBIS | c.168T>A p.N56K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV99809378; called by muse, mutect2, varscan2
- RBM26 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99935942; called by muse, mutect2, varscan2
- REG4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99858421; called by muse, mutect2, varscan2
- RERE | c.1513T>C p.Y505H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100555686; called by muse, mutect2, varscan2
- RERG | c.155_157del p.E52del | In Frame Del (DEL) | VAF 23/52 reads (44%) | catalogued as rs752288457; called by mutect2, pindel, varscan2
- REV3L | c.8842C>T p.R2948* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV62622412; called by muse, mutect2, varscan2
- RFX6 | c.1506del p.F502Lfs*5 | Frame Shift Del (DEL) | VAF 31/145 reads (21%) | catalogued as rs1176756248; called by mutect2, pindel, varscan2
- RNF213 | c.13550G>A p.G4517D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100300049; called by muse, mutect2, varscan2
- RNF216 | c.1382G>A p.R461Q (on ENST00000425013 / NM_207116.3; = p.R518Q on NM_207111.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs778183712, COSV66290460; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPGRIP1L | c.2990A>G p.E997G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100046027; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL4 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs771881549, COSV57178584; called by muse, mutect2, varscan2
- RPS6KL1 | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100665009; called by muse, mutect2, varscan2
- RSPO3 | c.599C>G p.T200R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV100759513; called by muse, mutect2, varscan2
- RSPRY1 | c.1168T>A p.Y390N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101070956; called by muse, mutect2, varscan2
- RUFY4 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100722986; called by muse, mutect2, varscan2
- RUNX3 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs947627767, COSV100136741; called by muse, mutect2, varscan2
- RUSC2 | c.2971C>T p.L991F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100770650; called by muse, mutect2, varscan2
- RXFP2 | c.2161del p.S721Vfs*9 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | catalogued as rs761227490; called by mutect2, varscan2
- SALL3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV101609960; called by mutect2, varscan2
- SART1 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV100408914; called by muse, mutect2, varscan2
- SBF1 | c.3825C>T p.H1275= | Splice Region (SNP) | VAF 47/63 reads (75%) | catalogued as rs762500203, COSV100817593; called by muse, mutect2, varscan2
- SDCBP | c.7_10del p.L3Ifs*7 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | catalogued as rs770879778; called by mutect2, varscan2
- SEC16A | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV99256922; called by muse, mutect2, varscan2
- SEC23B | c.315T>G p.N105K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99357536; called by mutect2, varscan2
- SECISBP2 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100068808; called by muse, mutect2, varscan2
- SEMA3D | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406200; called by muse, mutect2, varscan2
- SEMA3D | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.253); catalogued as COSV99406203; called by muse, mutect2, varscan2
- SETX | c.7895G>T p.R2632M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs1315385196, COSV99809181; called by muse, mutect2, varscan2
- SF1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV57117002, COSV99918086; called by muse, mutect2, varscan2
- SH3TC1 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as rs772809488, COSV55280823; called by muse, mutect2, varscan2
- SHROOM2 | c.4202C>T p.T1401M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs975946898, COSV101098338; called by muse, mutect2, varscan2
- SIN3A | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs749564136, COSV100845079; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs751442558; called by mutect2, varscan2
- SLAMF9 | c.520del p.D174Ifs*75 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs759108348; called by mutect2, pindel, varscan2
- SLC12A4 | c.3038A>G p.Q1013R | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99862905; called by muse, mutect2
- SLC25A45 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99587256; called by muse, mutect2
- SLC25A48 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99191953; called by muse, mutect2, varscan2
- SLC39A11 | c.573G>T p.W191C (on ENST00000542342 / NM_001159770.2; = p.W184C on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99722691; called by muse, mutect2, varscan2
- SLC39A3 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99514135; called by muse, mutect2
- SLITRK4 | c.1505A>G p.N502S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as COSV100567229; called by muse, mutect2, varscan2
- SMC5 | c.1674-2A>G p.X558_splice | Splice Site (SNP) | VAF 27/63 reads (43%) | catalogued as COSV100747005; called by muse, mutect2, varscan2
- SMG6 | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99557856, COSV99557927; called by muse, mutect2, varscan2
- SND1 | c.1243-1G>T p.X415_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100689986; called by muse, mutect2, varscan2
- SNRNP40 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1471089189, COSV99745189; called by muse, mutect2, varscan2
- SNX14 | c.338+1G>A p.X113_splice | Splice Site (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100121454; called by muse, mutect2, varscan2
- SOBP | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100432945; called by muse, mutect2, varscan2
- SORCS1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs780091835, COSV99544512; called by muse, mutect2, varscan2
- SP6 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs959616015, COSV100646970; called by muse, mutect2, varscan2
- SPEM2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV61604885; called by muse, mutect2, varscan2
- SPINT1 | c.1193G>T p.G398V (on ENST00000344051 / NM_181642.3; = p.G382V on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688939; called by muse, mutect2, varscan2
- SPRY1 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100201791; called by muse, mutect2, varscan2
- SPTAN1 | c.6906G>A p.M2302I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100823366; called by muse, mutect2, varscan2
- SPTBN2 | c.4632C>G p.I1544M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV100018609; called by muse, mutect2, varscan2
- SRM | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV100978940; called by muse, mutect2, varscan2
- SRRM1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100104281; called by muse, mutect2, varscan2
- SYCN | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59212261; called by muse, mutect2, varscan2
- SYNE1 | c.24397A>G p.N8133D (on ENST00000367255 / NM_182961.4; = p.N8062D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99557513; called by muse, mutect2, varscan2
- SYNE1 | c.23969G>T p.R7990M (on ENST00000367255 / NM_182961.4; = p.R7919M on NM_033071.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99557520; called by muse, mutect2, varscan2
- SYNE2 | c.3478C>T p.Q1160* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100647128; called by muse, mutect2, varscan2
- SYNM | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs112214271, COSV50443498; called by muse, mutect2, varscan2
- SZT2 | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.082); catalogued as COSV100986994; called by mutect2, varscan2
- TAC4 | c.317_318del p.E106Gfs*2 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs759826496; called by pindel, varscan2
- TACSTD2 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV100973731; called by muse, mutect2, varscan2
- TAF5 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as COSV100428217; called by muse, mutect2, varscan2
- TAF5L | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99272866; called by muse, mutect2, varscan2
- TBC1D12 | c.1123T>A p.C375S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1396706119, COSV99831279; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D24 | c.1252T>A p.F418I (on ENST00000646147 / NM_001199107.2; = p.F412I on NM_020705.3) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as COSV99564818; called by muse, mutect2, varscan2
- TBC1D2B | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs1435515527, COSV100316988; called by muse, mutect2
- TBPL2 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV55972641; called by muse, mutect2
- TCF7 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100389829; called by muse, mutect2, varscan2
- TECPR1 | c.2312G>T p.R771L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV101130317; called by muse, mutect2, varscan2
- TENM1 | c.7829C>T p.S2610F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100950444, COSV64429708; called by muse, mutect2, varscan2
- TENT4B | c.737T>A p.I246N (on ENST00000561678 / NM_001365323.2; = p.I231N on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100665805; called by muse, mutect2, varscan2
- TFB1M | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs937927856, COSV99265219; called by muse, mutect2, varscan2
- TGIF1 | c.385A>C p.N129H (on ENST00000330513 / NM_001374396.1; = p.N149H on NM_003244.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.753); catalogued as COSV100394770; called by muse, mutect2, varscan2
- THBS1 | c.3005A>C p.E1002A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as COSV99527722; called by muse, mutect2, varscan2
- THSD7B | c.4004A>T p.H1335L (on ENST00000272643; = p.H1333L on NM_001316349.2) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99746983; called by muse, mutect2, varscan2
- TLK1 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as rs1464153873, COSV99054512; called by muse, mutect2, varscan2
- TMEM129 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as rs756918029, COSV57559528; called by muse, mutect2, varscan2
- TMEM168 | c.1515C>A p.H505Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100454564; called by muse, mutect2, varscan2
- TMIE | c.308C>G p.T103R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.813); catalogued as COSV100167821; called by muse, mutect2, varscan2
- TNFRSF1B | c.985A>G p.S329G | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100884138; called by muse, mutect2, varscan2
- TNRC6B | c.2920G>T p.G974C (on ENST00000454349 / NM_001162501.2; = p.G227C on NM_001024843.1) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100109302; called by muse, mutect2, varscan2
- TP53BP1 | c.3669_3671del p.E1224del | In Frame Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs755965497; called by pindel, varscan2
- TRAC | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs749855873; called by muse, mutect2, varscan2
- TRAPPC10 | c.1186-1G>T p.X396_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99378347; called by muse, varscan2
- TRIM31 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100946763; called by muse, mutect2, varscan2
- TRIP10 | c.1479dup p.A494Rfs*2 (on ENST00000313244 / NM_001288962.2; = p.A438Rfs*2 on NM_004240.4) | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs762545513; called by mutect2, varscan2
- TRIP12 | c.3790C>T p.H1264Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1200470356, COSV99389577; called by muse, mutect2, varscan2
- TRPC5 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV53283771, COSV53303581; called by muse, mutect2, varscan2
- TRPM7 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57914384; called by muse, mutect2, varscan2
- TRPV1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs762747986, COSV99439049; called by muse, mutect2, varscan2
- TSC22D2 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100721202; called by muse, mutect2, varscan2
- TTC21A | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764077469, COSV99826766; called by muse, mutect2, varscan2
- TTC23 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100018466, COSV100018543, COSV50440549; called by muse, mutect2, varscan2
- TTC30A | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs1332442361, COSV100826156; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL7 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99552104; called by muse, mutect2, varscan2
- TTN | c.64237G>A p.A21413T (on ENST00000591111; = p.A13989T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | PolyPhen benign (0.439); catalogued as COSV100601334; called by muse, mutect2, varscan2
- TTN | c.34798G>T p.A11600S (on ENST00000591111; = p.A10673S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | PolyPhen benign (0); catalogued as COSV100601338; called by muse, mutect2, varscan2
- TUBB4A | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV51152526; called by muse, mutect2, varscan2
- TXLNG | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV101200562; called by muse, mutect2, varscan2
- UBA1 | c.2767A>G p.K923E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255548; called by muse, mutect2, varscan2
- UBE2E2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV100232616; called by muse, mutect2, varscan2
- UBE2K | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs199792616, COSV54693459; called by muse, mutect2, varscan2
- UBE2N | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100538600; called by muse, mutect2, varscan2
- UBE2O | c.3755C>A p.P1252H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772509610, COSV100039229; called by muse, mutect2, varscan2
- UBE4B | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99476062; called by muse, mutect2, varscan2
- UMODL1 | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV101253115; called by muse, mutect2, varscan2
- UMPS | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV51739421; called by muse, mutect2
- UPB1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs770476916, COSV100387103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USE1 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99812416; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs747493460; called by mutect2, varscan2
- USP34 | c.7673G>A p.R2558H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV68401521; called by muse, mutect2, varscan2
- UTP20 | c.6500C>T p.A2167V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.907); catalogued as COSV99881120; called by muse, mutect2, varscan2
- UTRN | c.9495T>C p.T3165= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100837820; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs762976381; called by mutect2, varscan2
- VCPIP1 | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs910694727, COSV100125447; called by muse, mutect2, varscan2
- VPS13C | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs756534061, COSV51422897; called by mutect2, varscan2
- VPS33B | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.123); catalogued as COSV100325483; called by muse, mutect2, varscan2
- VPS4A | c.113A>C p.Y38S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99651874; called by muse, mutect2
- VPS8 | c.4055del p.K1352Rfs*74 (on ENST00000625842 / NM_001349294.1; = p.K1350Rfs*74 on NM_015303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs1262463583, COSV54987482; called by mutect2, pindel, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs756173793; called by mutect2, varscan2
- WASHC2A | c.3998A>C p.D1333A | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254554; called by muse, mutect2, varscan2
- WASHC5 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100572686; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1158703313; called by mutect2, pindel, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDR62 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV99543367; called by muse, mutect2, varscan2
- WNT5B | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs748373948, COSV100148608; called by muse, mutect2, varscan2
- XKR4 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100531662; called by muse, mutect2, varscan2
- XKR5 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101306640; called by muse, mutect2, varscan2
- XPO4 | c.3380G>A p.R1127Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs762996054, COSV99688274; called by muse, mutect2, varscan2
- XPO6 | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100484907, COSV58964930; called by muse, mutect2, varscan2
- XRN1 | c.703del p.T235Hfs*19 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs779316292; called by mutect2, pindel, varscan2
- ZBTB11 | c.2105A>G p.Q702R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV100465276; called by muse, mutect2, varscan2
- ZBTB40 | c.792A>C p.K264N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100988856, COSV65144846; called by muse, mutect2, varscan2
- ZBTB7A | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as rs375560014; called by muse, varscan2
- ZC3H13 | c.1564T>C p.Y522H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV99667740; called by muse, mutect2, varscan2
- ZFAND5 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV99428445; called by muse, mutect2, varscan2
- ZFAND5 | c.482T>G p.V161G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99428446; called by muse, mutect2, varscan2
- ZFHX4 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs775789501, COSV50479220, COSV50859789; called by muse, mutect2, varscan2
- ZFP14 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54205301; called by muse, mutect2, varscan2
- ZFP41 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100414629; called by muse, mutect2, varscan2
- ZFP69 | c.835dup p.I279Nfs*10 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | catalogued as rs774870329; called by mutect2, pindel, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs751589999; called by mutect2, pindel, varscan2
- ZNF174 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV51903993; called by muse, mutect2, varscan2
- ZNF366 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as COSV100574155; called by muse, mutect2, varscan2
- ZNF425 | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV100955426; called by muse, mutect2, varscan2
- ZNF524 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs1404848070, COSV55608475; called by muse, mutect2
- ZNF583 | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.388); catalogued as rs765739164, COSV99382018; called by muse, varscan2
- ZNF608 | c.2758C>T p.H920Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100101330; called by muse, mutect2, varscan2
- ZNF800 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99757779; called by muse, mutect2, varscan2
- ZNF836 | c.1931G>A p.G644D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV100440734; called by muse, mutect2, varscan2
- ZNFX1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100446422; called by muse, mutect2, varscan2
- ZRANB3 | c.1597del p.R533Dfs*3 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs765112091; called by mutect2, pindel, varscan2
- AC005833.1 | c.1681_1682del p.W561Gfs*28 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.268del p.Q90Sfs*43 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | called by mutect2, varscan2
- ADCY1 | c.2234del p.F745Sfs*9 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, varscan2
- ADSS2 | c.473del p.N158Ifs*41 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- AP000311.1 | c.310del p.L104Sfs*5 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ARGLU1 | c.539_540del p.R180Tfs*3 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by pindel, varscan2
- ASIC1 | c.1063_1065del p.E355del | In Frame Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- B3GNT4 | c.836del p.G279Efs*34 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, pindel, varscan2
- BCL9L | c.95del p.P32Lfs*13 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- C3 | c.3021del p.S1008Rfs*8 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- CACNB2 | c.923dup p.L308Ffs*6 (on ENST00000324631 / NM_201596.3; = p.L253Ffs*6 on NM_000724.4) | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CELSR3 | c.4853del p.G1618Vfs*13 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- CNOT7 | c.532_534del p.E178del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- CPSF1 | c.373_375del p.E125del | In Frame Del (DEL) | VAF 12/75 reads (16%) | called by pindel, varscan2
- CSMD3 | c.3309del p.G1104Vfs*19 (on ENST00000297405 / NM_001363185.1; = p.G1000Vfs*19 on NM_052900.3) | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- CTCF | c.1179_1182del p.L394Kfs*4 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- CTSW | c.1003del p.A335Pfs*34 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- CWC25 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by mutect2, varscan2
- DDX3X | c.119_121del p.P40del (on ENST00000399959; = p.P41del on NM_001356.5) | In Frame Del (DEL) | VAF 37/125 reads (30%) | called by pindel, varscan2
- DENND4A | c.2398del p.M800Cfs*75 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- DMXL2 | c.7706del p.P2569Lfs*26 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- DYM | c.1262del p.N421Ifs*10 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- ESPL1 | c.4760del p.G1587Afs*66 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- ESRRB | c.689del p.P230Lfs*11 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- FAM81B | c.1258del p.L420Sfs*11 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- FBLN2 | c.686del p.P229Qfs*45 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- FILIP1 | c.113dup p.K39Efs*6 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- GLI2 | c.49del p.S17Vfs*29 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- GPANK1 | c.800del p.G267Afs*30 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- HDGF | c.603del p.S202Lfs*123 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- HEXA | c.946del p.Y316Ifs*24 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1206dup p.Q403Tfs*7 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, varscan2
- INPP1 | c.224del p.N75Ifs*20 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- INSR | c.4025del p.G1342Afs*23 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- IRF9 | c.856del p.R286Efs*62 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- JARID2 | c.1186del p.A396Rfs*18 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- KDM3A | c.2280_2281del p.S762Kfs*87 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by pindel, varscan2
- KMT2B | c.6413del p.P2138Rfs*15 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- LAMB1 | c.3647_3664del p.Y1216_D1221del | In Frame Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- LRRN2 | c.1705del p.A569Pfs*57 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- MAML2 | c.256del p.A86Qfs*54 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- MAP3K19 | c.2586_2588del p.K862del | In Frame Del (DEL) | VAF 5/25 reads (20%) | called by pindel, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- MARK1 | c.1452dup p.S485Ifs*7 | Frame Shift Ins (INS) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- MBD5 | c.2582_2583del p.T861Nfs*27 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by pindel, varscan2
- MBNL1 | c.218del p.P73Hfs*3 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- MBNL1 | c.1085del p.F362Sfs*12 (on ENST00000282486 / NM_207293.2; = p.F356Sfs*12 on NM_021038.5 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- MBOAT1 | c.213dup p.G72Wfs*31 | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- MPRIP | c.1057_1058del p.P353Sfs*43 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- NCOA1 | c.3472del p.R1158Vfs*33 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- NDUFC2 | c.206_207del p.F69Cfs*9 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, varscan2
- NEURL4 | c.1509del p.E504Rfs*38 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- NFIC | c.1367del p.P456Lfs*36 (on ENST00000443272 / NM_001245002.2; = p.P447Lfs*36 on NM_205843.3) | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- NHS | c.3596del p.N1199Tfs*6 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- NOS1 | c.2184del p.T729Qfs*11 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- NUP98 | c.3983dup p.N1328Kfs*18 (on ENST00000359171 / NM_001365126.1; = p.N1311Kfs*18 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- P3H3 | c.796del p.A266Lfs*54 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by pindel, varscan2
- PARD6A | c.602del p.G201Vfs*23 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- PCGF3 | c.193del p.L65Cfs*26 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- PCOLCE2 | c.711-3del | Splice Region (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- PDGFC | c.533del p.P178Lfs*13 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- PHACTR2 | c.587del p.N196Ifs*80 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, varscan2
- PHLDA3 | c.265del p.L89Wfs*12 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- PIDD1 | c.2308dup p.A770Gfs*58 | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- PLGRKT | c.183del p.F61Lfs*8 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, varscan2
- PPP1R36 | c.500del p.N167Tfs*12 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- RBBP6 | c.3625del p.I1209Sfs*47 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- RPRD2 | c.3824del p.P1275Lfs*138 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- SACS | c.10780_10783del p.I3594Ffs*15 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by pindel, varscan2
- SCLT1 | c.327del p.K109Nfs*11 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- SLAMF7 | c.829dup p.H277Pfs*15 | Frame Shift Ins (INS) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.19del p.E7Kfs*65 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- SREK1 | c.723del p.K241Nfs*34 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- SYNRG | c.2061G>C p.E687D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, varscan2
- THAP6 | c.171del p.G58Efs*23 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- TMPPE | c.1197dup p.N401Efs*40 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- TNPO2 | c.422_424del p.N141del | In Frame Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- TNRC18 | c.6317del p.G2106Vfs*3 | Frame Shift Del (DEL) | VAF 36/116 reads (31%) | called by mutect2, varscan2
- TNRC6B | c.2251del p.E751Rfs*41 | Frame Shift Del (DEL) | VAF 38/68 reads (56%) | called by mutect2, pindel, varscan2
- TOM1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- TRAV8-2 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TRHR | c.1143del p.V382Cfs*20 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TRMT1 | c.1431_1434del p.L478Pfs*8 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- TUBGCP2 | c.2647del p.Q883Kfs*25 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- UBXN4 | c.1135_1137del p.K379del | In Frame Del (DEL) | VAF 10/56 reads (18%) | called by pindel, varscan2
- UHRF1BP1L | c.3423del p.G1142Efs*17 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- WAS | c.982del p.R328Gfs*117 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- WIPF2 | c.545del p.P182Qfs*56 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- ZNF878 | c.712del p.S238Lfs*5 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.26del p.K9Sfs*10 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- ZSCAN18 | c.1462del p.A488Lfs*39 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- ABCC3 | c.1164C>T p.V388= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs777105338, COSV99558899; called by muse, mutect2, varscan2
- ACP7 | c.1242G>A p.S414= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs151134063; called by muse, mutect2, varscan2
- ADGRE3 | c.1611C>A p.L537= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99505978; called by muse, mutect2, varscan2
- ADRB3 | c.612C>T p.Y204= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs778036430, COSV100799808; called by muse, mutect2, varscan2
- AGRP | c.228G>A p.L76= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99341025; called by muse, mutect2, varscan2
- ALG13 | c.3084C>T p.T1028= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs758300150, COSV99321848; ClinVar: likely benign; called by muse, varscan2
- ANK1 | c.1842G>A p.Q614= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99224539; called by muse, mutect2, varscan2
- AQP3 | c.364C>T p.L122= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99955527; called by muse, mutect2, varscan2
- ARAP3 | c.4209C>T p.Y1403= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs144642444; called by muse, mutect2, varscan2
- ARHGEF10L | c.1323G>A p.R441= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99392321; called by muse, mutect2, varscan2
- ASTN2 | c.999G>A p.V333= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs771968340, COSV100525695; called by muse, mutect2, varscan2
- ATP2B1 | c.2553C>T p.S851= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV53805611, COSV99665380; called by muse, mutect2, varscan2
- ATP7B | c.2946C>A p.A982= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99666202; called by muse, mutect2
- BCL2L12 | c.978C>T p.P326= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs759969547, COSV99880953; called by muse, mutect2, varscan2
- BRD4 | c.3855G>A p.Q1285= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99650153; called by muse, mutect2, varscan2
- C1orf112 | c.928C>T p.L310= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99609538; called by muse, mutect2, varscan2
- C21orf58 | c.573G>A p.P191= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs766961178, COSV99387943; called by muse, mutect2, varscan2
- CA5A | c.885C>A p.S295= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV99990487; called by muse, mutect2, varscan2
- CAPRIN2 | c.672G>A p.L224= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99195452; called by muse, mutect2, varscan2
- CATSPERD | c.1386G>A p.Q462= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100486716; called by muse, mutect2, varscan2
- CCDC171 | c.2790T>C p.S930= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV99900125; called by muse, mutect2, varscan2
- CDH5 | c.1470C>T p.N490= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs370750196; called by muse, mutect2, varscan2
- CDKL3 | c.1305A>G p.L435= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99527717; called by muse, mutect2, varscan2
- CEP120 | c.2913C>A p.L971= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100070962; called by muse, mutect2, varscan2
- CFHR4 | c.111T>C p.S37= (on ENST00000367416 / NM_001201551.2; = p.S38= on NM_006684.5) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99259904; called by muse, mutect2, varscan2
- CHPF2 | c.2170C>T p.L724= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV99222966; called by muse, mutect2, varscan2
- CIT | c.2865G>A p.Q955= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV99948216; called by muse, mutect2, varscan2
- CLDN5 | c.9C>A p.S3= (on ENST00000618236 / NM_001363066.2; = p.S88= on NM_003277.4) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99596527; called by muse, mutect2, varscan2
- CNGB1 | c.3289C>T p.L1097= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs757504870, COSV99202255; called by muse, mutect2, varscan2
- COL22A1 | c.1137C>T p.H379= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100277194; called by muse, mutect2, varscan2
- CRACR2B | c.375G>A p.A125= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1179994082, COSV100351981; called by muse, mutect2, varscan2
- CRB2 | c.99G>A p.T33= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs537988083, COSV63501870; called by muse, mutect2, varscan2
- CREBBP | c.4992C>T p.R1664= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs756979739, COSV52123103; called by muse, mutect2, varscan2
- CREBRF | c.111G>A p.S37= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs376606038; called by muse, mutect2, varscan2
- CRYAB | c.84C>T p.F28= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1555165581, COSV57052905; called by muse, mutect2, varscan2
- CSMD2 | c.6828A>G p.A2276= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99587556; called by muse, mutect2, varscan2
- CSNK1G2 | c.882G>T p.V294= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- DDHD2 | c.1254A>G p.L418= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1445658991, COSV101240569; called by muse, mutect2, varscan2
- DDX60 | c.2877C>T p.A959= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs546918985, COSV101190316; called by muse, mutect2, varscan2
- DMXL1 | c.4653C>A p.T1551= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs749627848, COSV100223591; called by muse, mutect2, varscan2
- DNAH11 | c.9648C>A p.T3216= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100178224; called by mutect2, varscan2
- DOCK8 | c.2883T>C p.H961= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101209859; called by muse, mutect2, varscan2
- EGF | c.1263T>C p.C421= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99490650; called by muse, mutect2
- ELP1 | c.3477C>T p.H1159= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs141257064; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA4 | c.1803G>A p.T601= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as rs140279818; called by muse, mutect2, varscan2
- EXOC3 | c.228G>A p.Q76= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs910625876, COSV100155218; called by muse, mutect2
- EXOC8 | c.1954T>C p.L652= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99149586; called by muse, mutect2
- FAR2 | c.960C>A p.V320= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99478623, COSV99478879; called by muse, mutect2, varscan2
- FARP1 | c.648A>G p.L216= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100130006; called by muse, mutect2, varscan2
- FOXA1 | c.1302C>T p.P434= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51645242; called by muse, mutect2, varscan2
- GCDH | c.765G>A p.S255= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1193455540, COSV99535794; ClinVar: likely benign; called by muse, mutect2, varscan2
- GIT2 | c.741T>C p.F247= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs752668461, COSV100188894; called by muse, mutect2, varscan2
- GLI1 | c.2247C>A p.G749= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57362135, COSV99953840; called by muse, mutect2, varscan2
- GLI3 | c.3384C>T p.D1128= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1301296601, COSV101229778; called by muse, mutect2, varscan2
- GON4L | c.2157C>A p.A719= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99673763; called by muse, mutect2, varscan2
- GRIN2A | c.2178C>T p.D726= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1391662912, COSV58018522; called by muse, mutect2, varscan2
- GUCY2D | c.909G>A p.R303= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs772311336, COSV99643841; called by muse, varscan2
- GUCY2D | c.1942C>T p.L648= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99643842; called by muse, mutect2, varscan2
- HDAC4 | c.2973C>T p.A991= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100612945; called by muse, mutect2, varscan2
- HERC2 | c.10938C>T p.C3646= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99871931; called by muse, mutect2, varscan2
- HK1 | c.159G>T p.R53= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100065870, COSV53866561; called by muse, mutect2, varscan2
- HSPA1A | c.1653C>T p.S551= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1344229710, COSV100989359; called by muse, mutect2, varscan2
- HSPA2 | c.462G>A p.S154= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs757713919, COSV55970597, COSV99904781; called by muse, mutect2, varscan2
- HSPA6 | c.1593T>C p.D531= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100554012; called by mutect2, varscan2
- HTR1E | c.78C>T p.C26= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs140190384, COSV100541012; called by muse, mutect2, varscan2
- IGF2BP1 | c.1017C>T p.A339= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1296602010, COSV99288416; called by muse, mutect2, varscan2
- IGSF9 | c.3225C>T p.S1075= (on ENST00000368094 / NM_001135050.2; = p.S1059= on NM_020789.4) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748288052, COSV100231018; called by muse, mutect2, varscan2
- IQGAP1 | c.1746G>A p.T582= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs201387133; called by muse, mutect2, varscan2
- IRAK1 | c.1446C>T p.P482= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs782657654, COSV100888964; called by muse, mutect2, varscan2
140 further variants in this file (0 protein-altering or splice-affecting, 120 silent, 20 other) are not listed here.
